TCGA case TCGA-16-1047 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Toronto Western Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e8688f7-bf69-432b-a5ac-4f5f4d5c10ba

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Dead; Days to death: 139 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 66.5 years (24,301 days); Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; Prior malignancy: yes; Prior treatment: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 66.6 years (24,326 days); Days to diagnosis: 25 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (2 entries)
- Day 25 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Days to progression: 25 days.
- Days to follow up: 139 days; Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-16-1047-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.3; Intermediate dimension: 0.2; Shortest dimension: 0.2.
  Slide TCGA-16-1047-01B-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0.
  Slide TCGA-16-1047-01B-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 40.
- Sample TCGA-16-1047-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: Yes; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.

GDC annotations on this case (curator notes; quoted as recorded):
- Case submitted is found to be a recurrence after submission: Per enrollment form, patient had a prior diagnosis of a lower grade glioma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 139 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 139 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 25 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-16-1047-01): tumor purity 0.91, ploidy 1.93, whole-genome doublings 0 (call status: legacy_call).
